Somatic mutation profile of tumor specimen TCGA-AB-2878-03A (aliquot TCGA-AB-2878-03A-01W-0732-08) from TCGA case TCGA-AB-2878, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 47.9 years (17,501 days).
Specimen TCGA-AB-2878-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 174d382c-c2da-4525-b578-c8d5dd8457ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2878-11A (Solid Tissue Normal), aliquot TCGA-AB-2878-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/534371d7-8ac4-46df-a044-6b12af4a7c27

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RIT1 | c.270G>A p.M90I | Missense Mutation (SNP) | VAF 61/121 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs483352822, CM136419, CM148229, COSV64170809, COSV64170843, COSV64170960; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- CACNA1E | c.4520A>G p.E1507G | Missense Mutation (SNP) | VAF 146/344 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV62417306; called by muse, mutect2, varscan2
- CHD4 | c.3478C>T p.R1160W (on ENST00000357008 / NM_001363606.2; = p.R1173W on NM_001273.5) | Missense Mutation (SNP) | VAF 116/262 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58910147; called by muse, mutect2, varscan2
- FBN1 | c.2290G>A p.V764I | Missense Mutation (SNP) | VAF 84/217 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs769641351, COSV57329048; called by muse, mutect2, varscan2
- NR2E1 | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV64562701; called by muse, mutect2, varscan2
- SPDYA | c.16A>C p.M6L | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61857359; called by muse, mutect2, varscan2
- STT3B | c.380A>G p.D127G | Missense Mutation (SNP) | VAF 131/325 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55505864; called by muse, varscan2
- VPS72 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 163/389 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV63168144; called by muse, mutect2, varscan2
- CACNA1F | c.858G>A p.S286= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs782458058; called by muse, mutect2
- MTMR10 | c.9C>T p.S3= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs745392185; called by muse, varscan2
- THEMIS2 | c.108G>A p.E36= | Silent (SNP) | VAF 18/466 reads (4%) | called by muse, mutect2
